Somatic mutation profile of tumor specimen MMRF_2717_1_BM_CD138pos (aliquot MMRF_2717_1_BM_CD138pos_T1_KHS5U_L14832) from MMRF case MMRF_2717, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2717_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eb08a21-f2ba-461a-b21a-0ef468a90d7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2717_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2717_1_PB_WBC_C2_KHS5U_L14833; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f224abc-58b4-49d9-bf29-2f9a0b94b762

The open-access MAF lists 100 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 24, Intron 12, Silent 10, 5'UTR 9, 5'Flank 3, RNA 2, Nonsense Mutation 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/156 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC154 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs780846385, COSV101209700; called by muse, mutect2, varscan2
- CYGB | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs779650045, COSV99506281; called by muse, mutect2, varscan2
- DNAH8 | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs940191116; called by muse, mutect2, varscan2
- DROSHA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs762001670, COSV60773292; called by muse, mutect2, varscan2
- EYS | c.4820C>A p.S1607Y | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100426625; called by muse, mutect2, varscan2
- FOXP4 | c.1391C>T p.A464V (on ENST00000307972 / NM_001012426.1; = p.A451V on NM_138457.3) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57220047; called by muse, mutect2, varscan2
- IRX2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57411443; called by muse, mutect2, varscan2
- LRP8 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs1165378015; called by muse, mutect2
- OR4K17 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1233091015; called by muse, mutect2
- PTPN14 | c.3178C>A p.H1060N | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs199690849, COSV99055873; called by muse, mutect2, varscan2
- SGCZ | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs138916610; called by muse, mutect2, varscan2
- SNX13 | c.358T>G p.Y120D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101285061; called by muse, mutect2, varscan2
- ZBTB17 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV65270452; called by muse, mutect2, varscan2
- ZSCAN5A | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54232322; called by muse, mutect2
- APLNR | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCL19 | c.63T>A p.S21R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CDKN1C | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- FMR1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUWE1 | c.2261+1G>A p.X754_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- IZUMO3 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- KLHL1 | c.1413A>C p.K471N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- KRT9 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRGUK | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- LRP1B | c.1542G>T p.R514S | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MYO3B | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NECTIN4 | c.704G>T p.R235M | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NLGN2 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NLGN4Y | c.1568T>G p.V523G | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13C5 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PCDH12 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- PRG4 | c.2913C>A p.F971L | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- RAG1 | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RHOBTB1 | c.1439G>A p.S480N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2
- SLC11A1 | c.1420G>T p.V474L | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC11A1 | c.1421T>G p.V474G | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC2A14 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TRBV6-1 | c.198T>G p.Y66* | Nonsense Mutation (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- ZNF462 | c.1973G>C p.S658T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); called by muse, mutect2
- BAZ2B | c.6024A>G p.V2008= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- EMB | c.81G>T p.A27= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1260074902; called by muse, mutect2, varscan2
- IGLV3-1 | c.153T>A p.A51= | Silent (SNP) | VAF 35/193 reads (18%) | catalogued as rs571682243; called by muse, varscan2
- OR10H5 | c.360C>T p.Y120= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs772836837, COSV58277328; called by muse, mutect2
- PCLO | c.9414A>C p.P3138= | Silent (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2, varscan2
- SLC13A4 | c.1359C>A p.I453= | Silent (SNP) | VAF 20/200 reads (10%) | called by muse, mutect2
- URB1 | c.5211A>G p.A1737= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- ZEB2 | c.3198C>T p.H1066= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ZFPM2 | c.843T>C p.A281= | Silent (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- ZNF200 | c.1035C>T p.F345= | Silent (SNP) | VAF 116/434 reads (27%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27240734 C>G | 5'Flank (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- ACER3 | c.*4841G>T | 3'UTR (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.*52G>A | 3'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as rs372201358; called by muse, mutect2, varscan2
- AL356585.2 | n.1464A>T | RNA (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021405 G>A | 5'Flank (SNP) | VAF 34/156 reads (22%) | catalogued as rs1378568121; called by muse, varscan2
- BCL7A | chr12:122021478 A>G | 5'Flank (SNP) | VAF 26/226 reads (12%) | catalogued as COSV55849186; called by muse, varscan2
- CLEC16A | c.2641+111C>A | Intron (SNP) | VAF 17/298 reads (6%) | called by muse, mutect2
- CPLX3 | c.*1098G>T | 3'UTR (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- CPM | c.*5171T>C | 3'UTR (SNP) | VAF 24/90 reads (27%) | catalogued as rs887552745; called by muse, mutect2, varscan2
- CSMD3 | c.-62A>C | 5'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- CYP4B1 | c.*59C>T | 3'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as rs1267619382; called by muse, mutect2
- DDX60L | c.*231G>A | 3'UTR (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2
- EPHA3 | c.*379G>C | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- EPS8 | c.*403A>G | 3'UTR (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- FAM155B | c.*54C>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- FAM227A | c.*2982A>C | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- FAR2 | c.*248G>T | 3'UTR (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- FMO9P | n.589G>T | RNA (SNP) | VAF 52/212 reads (25%) | called by muse, mutect2, varscan2
- GALNT10 | c.1056+1392_1056+1393del | Intron (DEL) | VAF 3/30 reads (10%) | catalogued as rs777969382, COSV51721232; called by pindel, varscan2*
- GASK1B | c.*280T>C | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- GCC2 | c.4229+108T>C | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs974928063; called by muse, varscan2
- GFOD1 | c.*2808C>G | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- GPNMB | c.541+746A>T | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- H3C1 | c.-2T>G | 5'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- IBTK | c.*314A>G | 3'UTR (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ITGAE | c.3085-40T>C | Intron (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- KCNC2 | c.*2145C>G | 3'UTR (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- KIAA0895 | c.179-9357G>T | Intron (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- MMP16 | c.*7049G>T | 3'UTR (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- MPC1 | c.-26A>G | 5'UTR (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- MYO1E | c.-95del | 5'UTR (DEL) | VAF 33/140 reads (24%) | catalogued as rs1484292271, COSV55682981; called by mutect2, pindel, varscan2
- MYO5C | c.4538-31G>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs376962592; called by muse, mutect2
- NAP1L4 | c.-18+982G>A | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- NET1 | c.*332A>G | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1458472098; called by muse, mutect2
- NLGN2 | c.*1535G>A | 3'UTR (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- OVOL1 | c.*698A>T | 3'UTR (SNP) | VAF 5/84 reads (6%) | catalogued as COSV60119486; called by muse, mutect2
- PCDH11X | c.3033+4411A>T | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- PCDHA8 | c.-71A>G | 5'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- PSIP1 | c.-86G>A | 5'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- PSMC3 | c.-47del | 5'UTR (DEL) | VAF 95/260 reads (37%) | called by mutect2, pindel, varscan2
- RALGAPA2 | c.*3614C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- SCYL3 | chr1:169853002 C>T | 3'Flank (SNP) | VAF 14/298 reads (5%) | catalogued as COSV99609375; called by muse, mutect2
- SLC35C2 | c.-89C>G | 5'UTR (SNP) | VAF 71/346 reads (21%) | called by muse, mutect2, varscan2
- SUN1 | c.*246A>G | 3'UTR (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1203+34A>C | Intron (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TJP3 | c.-9-6544C>A | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- TLE4 | c.-82G>A | 5'UTR (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- UTRN | c.79+52346A>C | Intron (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.*335G>T | 3'UTR (SNP) | VAF 2/28 reads (7%) | called by muse, mutect2
- ZNF385D | c.*1405A>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ZNF493 | c.*1499A>T | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
